Gene-level copy-number profile of tumor specimen TCGA-05-4390-01A from TCGA case TCGA-05-4390, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.7 years (21,430 days).
Specimen TCGA-05-4390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1c3f76ca-a0f5-4b4c-8438-7eea1c5e161f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4390-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/74ad8bf8-b0b5-482e-9bd0-3290681954d4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,699; copy number 3: 16,603; copy number 4: 17,794; copy number 5: 9,020; copy number 6: 6,433; copy number 7: 2,156; copy number 8: 672; copy number 9: 645; copy number 10: 1,818; copy number 11: 376; copy number 14: 569; copy number 15: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4390-01A-02D-1752-01): tumor purity 0.57, ploidy 3.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,435 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,655,205–39,493,095, 7 genes, copy number 10 (within-gene range 8–10): KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1.
- chr7:49,524,208–57,485,895, 186 genes, copy number 10 (broad region; genes not listed).
- chr8:37,421,341–145,066,685, 1,702 genes, copy number 9–14 (within-gene range 3–14) (broad region; genes not listed).
- chr9:87,799,501–88,485,325, 28 genes, copy number 10–15 (within-gene range 2–15): AL772337.4, FBP2P1, ELF2P3, NPAP1P7, CTSLP8, AL772337.2, AL772337.1, AL772337.3, SPATA31E1, SPATA31C1, AL353572.2, AL353572.3, CDK20, RNU6-86P, RPS10P3, AL353572.4, AL353572.1, SPATA31C2, AL353726.1, AL353726.2, AL451142.1, AL451142.2, RPSAP49, AL353748.3, SPIN1, AL353748.2, HNRNPA1P14, AL353748.1.
- chr9:90,158,028–91,427,144, 21 genes, copy number 11–14: AL353649.1, OR7E31P, OR7E116P, LINC01508, LINC01501, DIRAS2, OR7E109P, OR7E108P, SYK, AL162585.1, AL355607.1, AL355607.2, AL158071.3, AL158071.2, LINC00484, LINC00484, AL158071.1, AL158071.4, AUH, NFIL3, AL353764.1.
- chr14:21,918,188–72,894,116, 1,058 genes, copy number 9–10 (broad region; genes not listed).
- chr14:72,929,612–72,929,930, 1 gene, copy number 10: AC007160.1.
- chr14:87,251,103–94,646,994, 154 genes, copy number 9 (broad region; genes not listed).
- chr18:20,946,906–39,800,322, 278 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
